Gene-level copy-number profile of tumor specimen ALCH-AC5E-TTP1-A from ALCHEMIST case ALCH-AC5E, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 57.6 years (21,048 days).
Specimen ALCH-AC5E-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ad7cea26-e7d5-46ec-883b-810859d739e1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AC5E-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/00f160a0-7c5e-43fa-b0a9-44098a95e625

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 8,245; copy number 2: 46,699; copy number 3: 3,388; copy number 4: 16.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:130,129,621–130,198,439, 5 genes: MED15P9, CCDC74B, SMPD4, MZT2B, TUBA3E.
- chr9:61,659,733–61,666,386, 2 genes: AL935212.1, AL935212.2.
- chr9:61,898,805–61,945,136, 2 genes: FAM242E, CR769775.1.
- chr9:131,021,168–131,021,306, 1 gene (within-gene range 0–1): AL583807.1.
- chr9:138,177,426–138,179,774, 1 gene: AL591424.2.
- chr15:25,169,337–25,250,940, 45 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr16:75,245,994–75,250,077, 1 gene (within-gene range 0–2): AC009078.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,901. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
